Somatic mutation profile of tumor specimen C3N-01171-03 (aliquot CPT0095190009) from CPTAC case C3N-01171, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 82.5 years (30,148 days).
Specimen C3N-01171-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a707c517-fc68-4791-aeb7-671aa53a0581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01171-31 (Blood Derived Normal), aliquot CPT0095220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20d6591c-f2a2-4465-b54f-36dc754c883c

The open-access MAF lists 890 somatic variants for this specimen: 595 protein-altering or splice-affecting, 171 silent, 124 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 387, Silent 171, Frame Shift Del 135, Intron 68, Frame Shift Ins 33, Nonsense Mutation 21, 5'UTR 17, 3'UTR 16, RNA 11, In Frame Del 9, 5'Flank 7, 3'Flank 5.

Variants (750 of 890; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 91/262 reads (35%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 26/150 reads (17%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CENPF | c.5920dup p.T1974Nfs*9 | Frame Shift Ins (INS) | VAF 20/126 reads (16%) | catalogued as rs757531591; ClinVar: pathogenic; called by mutect2, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 30/172 reads (17%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel
- KMT2D | c.9265dup p.V3089Gfs*9 | Frame Shift Ins (INS) | VAF 67/354 reads (19%) | catalogued as rs1333678798; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MTM1 | c.969dup p.V324Sfs*8 | Frame Shift Ins (INS) | VAF 35/154 reads (23%) | catalogued as rs587783865; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 22/126 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ROS1 | c.4601del p.N1534Ifs*69 | Frame Shift Del (DEL) | VAF 42/184 reads (23%) | catalogued as rs776274768; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 61/214 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 172/602 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3593C>T p.A1198V | Missense Mutation (SNP) | VAF 47/188 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.751); catalogued as rs774580071; called by muse, mutect2, varscan2
- AC004922.1 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53163824; called by muse, mutect2
- AC073610.2 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 116/457 reads (25%) | SIFT tolerated, low confidence (0.62); catalogued as rs1398846470; called by muse, mutect2, varscan2
- AC090517.4 | c.1783del p.S595Vfs*7 | Frame Shift Del (DEL) | VAF 49/164 reads (30%) | catalogued as rs1157171684; called by mutect2, pindel, varscan2
- AC090517.4 | c.956del p.N319Ifs*6 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | catalogued as COSV51001721; called by mutect2, pindel, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs757016425; called by mutect2, varscan2
- ACIN1 | c.3751C>T p.R1251W | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV52977594; called by muse, varscan2
- ACSF2 | c.1514T>C p.I505T | Missense Mutation (SNP) | VAF 13/315 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1245511765; called by muse, mutect2
- ACTN2 | c.1626G>A p.M542I | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.596); catalogued as rs1193302872, COSV63974716; called by muse, varscan2
- ADCK1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as rs766848926, COSV53083782; called by muse, mutect2, varscan2
- ADGRG1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 38/462 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs759353835, CM093540; called by muse, mutect2
- ADGRL2 | c.2101G>A p.A701T (on ENST00000370717 / NM_001366005.1; = p.A688T on NM_012302.4) | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs759899407, COSV54653894, COSV54693439; called by muse, varscan2
- AGO2 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1205353566, COSV99596260; called by muse, mutect2, varscan2
- AGPAT4 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 158/536 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs781252538, COSV57248906; called by muse, mutect2, varscan2
- AKAP3 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs199800327, COSV57417467; called by muse, mutect2, varscan2
- AKT2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 100/333 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs930976777; called by muse, mutect2, varscan2
- AMBRA1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54051543; called by muse, mutect2, varscan2
- ANO8 | c.1087del p.L363Cfs*24 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | catalogued as COSV50178856; called by mutect2, pindel, varscan2
- AP3B2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as rs1567270395; called by muse, mutect2, varscan2
- APEH | c.870del p.K291Sfs*17 | Frame Shift Del (DEL) | VAF 96/393 reads (24%) | catalogued as rs768993340, COSV56533158; called by mutect2, pindel, varscan2
- APEX1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.363); catalogued as rs777188321; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 38/193 reads (20%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP33 | c.1961del p.G654Efs*34 | Frame Shift Del (DEL) | VAF 47/181 reads (26%) | catalogued as rs1378832725; called by mutect2, pindel, varscan2
- ARHGAP39 | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745537238; called by muse, mutect2, varscan2
- ARHGAP5 | c.576dup p.P193Tfs*8 | Frame Shift Ins (INS) | VAF 48/135 reads (36%) | catalogued as rs1269856893; called by mutect2, varscan2
- ARMCX3 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as rs1041715655; called by muse, mutect2, varscan2
- ATP8A2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54935014, COSV54970485; called by muse, mutect2
- BCS1L | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1004879625, COSV55308087; called by muse, mutect2, varscan2
- BRCA1 | c.4796C>T p.A1599V | Missense Mutation (SNP) | VAF 136/495 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs749702730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP1 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs548039356; called by muse, mutect2, varscan2
- BRINP3 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 105/332 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs146936488; called by muse, mutect2, varscan2
- BRSK1 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs200073194; called by muse, mutect2, varscan2
- C16orf78 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373637026, COSV54558555; called by muse, mutect2, varscan2
- C8orf89 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs544497100, COSV63481096; called by muse, mutect2, varscan2
- CACNA1C | c.3235G>A p.G1079R | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781440831, COSV59766943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.3545G>A p.R1182H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs376174454; called by muse, mutect2, varscan2
- CACNA1G | c.6142C>T p.P2048S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV61729477; called by muse, mutect2
- CASP8AP2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.784); catalogued as rs377049861; called by muse, mutect2, varscan2
- CATSPER4 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs376375618, COSV58794643; called by muse, mutect2, varscan2
- CBX7 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs768579626, COSV99334048; called by muse, mutect2, varscan2
- CCDC136 | c.1328A>G p.Q443R | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV52804726; called by muse, mutect2, varscan2
- CCDC153 | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 43/247 reads (17%) | catalogued as rs745729530; called by mutect2, pindel, varscan2
- CCDC190 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1311407331, COSV100905829; called by muse, mutect2, varscan2
- CCS | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs367642079, COSV100039972; called by muse, mutect2, varscan2
- CD300C | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.868); catalogued as rs1355890412; called by muse, mutect2, varscan2
- CDC42BPG | c.3901G>A p.V1301M | Missense Mutation (SNP) | VAF 108/393 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764530358, COSV61345534; called by muse, mutect2, varscan2
- CELF4 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100611620; called by muse, mutect2, varscan2
- CELF6 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs964375764; called by muse, mutect2, varscan2
- CENPT | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as rs778462309; called by muse, varscan2
- CEP89 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs141289026; called by muse, mutect2, varscan2
- CFAP43 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs757395054; called by muse, mutect2, varscan2
- CHML | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 99/390 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs199932635, COSV104405504; called by muse, mutect2, varscan2
- CHML | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs777997687, COSV100087852; called by muse, mutect2, varscan2
- CHST7 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1269676728; called by muse, mutect2, varscan2
- CIC | c.3743del p.P1248Hfs*54 | Frame Shift Del (DEL) | VAF 24/147 reads (16%) | catalogued as COSV50671496; called by mutect2, pindel, varscan2
- CLASRP | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as rs1484058541; called by muse, varscan2
- CLEC1B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 157/483 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753263519, COSV53726856; called by muse, mutect2, varscan2
- CLIC6 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs775957352; called by muse, mutect2, varscan2
- CNOT3 | c.387G>A p.T129= | Splice Region (SNP) | VAF 28/85 reads (33%) | catalogued as COSV55361055; called by muse, mutect2, varscan2
- CNOT6 | c.750del p.L251Wfs*2 | Frame Shift Del (DEL) | VAF 25/134 reads (19%) | catalogued as COSV56160927; called by mutect2, pindel, varscan2
- CNTROB | c.2699del p.G900Efs*34 | Frame Shift Del (DEL) | VAF 37/154 reads (24%) | catalogued as rs35508310, COSV66608279; called by mutect2, pindel, varscan2
- COG5 | c.2198C>T p.T733M (on ENST00000347053 / NM_001379512.1; = p.T754M on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/500 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs760602600, COSV51766287; called by muse, mutect2, varscan2
- COL12A1 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.683); catalogued as rs369193482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL15A1 | c.2146del p.V716Sfs*36 | Frame Shift Del (DEL) | VAF 19/163 reads (12%) | catalogued as COSV66642911, COSV66650032; called by mutect2, pindel, varscan2
- COL5A2 | c.4021C>T p.P1341S | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66412357; called by muse, mutect2, varscan2
- COL6A3 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 91/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs780201464, COSV55094333; called by muse, mutect2, varscan2
- CPAMD8 | c.3153del p.H1052Ifs*127 (on ENST00000651564; = p.H1005Ifs*127 on NM_015692.5) | Frame Shift Del (DEL) | VAF 62/256 reads (24%) | catalogued as rs750161916, COSV71597321; called by mutect2, pindel, varscan2
- CPTP | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as rs748747267; called by muse, mutect2, varscan2
- CRB3 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 94/345 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756596803, COSV100375409; called by muse, mutect2, varscan2
- CROCC | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 43/733 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as rs772382949, COSV65010741; called by muse, mutect2
- CROCC | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); catalogued as rs755588921; called by muse, mutect2, varscan2
- CTNNA3 | c.1175C>T p.T392M | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146777494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTR9 | c.2978del p.K993Rfs*12 | Frame Shift Del (DEL) | VAF 38/228 reads (17%) | catalogued as COSV99057763; called by mutect2, varscan2
- DACH1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.434); catalogued as rs541920655; called by muse, mutect2, varscan2
- DAPK3 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs1190048528, COSV56663236; called by muse, mutect2, varscan2
- DDX39A | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375284806; called by muse, mutect2, varscan2
- DDX60L | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs368623576; called by muse, mutect2, varscan2
- DENND1C | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.561); catalogued as COSV67373928; called by muse, mutect2, varscan2
- DIRAS1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs775310063, COSV60216413; called by muse, mutect2, varscan2
- DIS3L | c.1132C>T p.R378* (on ENST00000319212 / NM_001143688.3; = p.R295* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as rs893215526, COSV59911391; called by muse, mutect2, varscan2
- DMKN | c.1168_1170del p.L390del | In Frame Del (DEL) | VAF 24/140 reads (17%) | catalogued as rs1293825246; called by pindel, varscan2
- DNAH5 | c.9947del p.P3316Lfs*22 | Frame Shift Del (DEL) | VAF 141/488 reads (29%) | catalogued as rs1206989225; called by mutect2, varscan2
- DNTT | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779136442, COSV100960684, COSV64523888; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DSG1 | c.2596G>C p.E866Q | Missense Mutation (SNP) | VAF 90/311 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99935914; called by muse, mutect2, varscan2
- DSG1 | c.3133G>A p.V1045M | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs140838956; called by muse, mutect2, varscan2
- DSG4 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.601); catalogued as COSV57389501; called by muse, mutect2, varscan2
- DYRK4 | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs760294743; called by muse, mutect2, varscan2
- ECEL1 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 112/397 reads (28%) | catalogued as rs1194638532; called by muse, mutect2, varscan2
- EHBP1L1 | c.3464G>C p.G1155A | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV58573306; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as rs761717176; called by mutect2, varscan2
- EPB41L2 | c.2008C>T p.R670* | Nonsense Mutation (SNP) | VAF 29/164 reads (18%) | catalogued as rs758533330; called by muse, mutect2, varscan2
- EPB41L3 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 88/336 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs749541572; called by muse, mutect2, varscan2
- EPHA10 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as rs781544726, COSV60402475; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 22/110 reads (20%) | catalogued as rs756461692; called by mutect2, varscan2
- ERBIN | c.3110G>A p.R1037Q | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.342); catalogued as rs749390226, COSV52315185; called by muse, mutect2, varscan2
- ERC1 | c.266T>C p.M89T | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as rs1318871501; called by muse, mutect2
- EVC2 | c.2216T>C p.L739P | Missense Mutation (SNP) | VAF 166/561 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60399113; called by muse, mutect2, varscan2
- EXOC3L4 | c.687del p.D230Tfs*205 | Frame Shift Del (DEL) | VAF 23/164 reads (14%) | catalogued as rs1225687649; called by mutect2, pindel, varscan2
- EYS | c.1674G>T p.W558C | Missense Mutation (SNP) | VAF 76/316 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as CM102716; called by muse, mutect2, varscan2
- FAAP100 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs566267727; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 44/221 reads (20%) | catalogued as rs751966944; called by mutect2, varscan2
- FAM124A | c.299C>T p.A100V (on ENST00000322475 / NM_001242312.2; = p.A136V on NM_145019.4) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1199449649; called by muse, mutect2
- FAM160A2 | c.1609C>T p.R537W (on ENST00000449352 / NM_001098794.2; = p.R551W on NM_032127.4) | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs148185483; called by muse, mutect2, varscan2
- FAM184B | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV53956796; called by muse, mutect2
- FAM20A | c.1166_1168del p.N389del | In Frame Del (DEL) | VAF 106/438 reads (24%) | catalogued as rs777704104; called by pindel, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FANCI | c.2635C>T p.R879* | Nonsense Mutation (SNP) | VAF 72/220 reads (33%) | catalogued as rs1013628944, CM154126, COSV104406978; called by muse, mutect2, varscan2
- FAT3 | c.12926C>T p.A4309V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV53091052; called by muse, mutect2, varscan2
- FAT4 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201106660; called by muse, mutect2, varscan2
- FBL | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 26/206 reads (13%) | catalogued as rs781092751, COSV99695341; called by muse, mutect2, varscan2
- FBN2 | c.4594G>T p.D1532Y | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52500653; called by muse, mutect2, varscan2
- FCN2 | c.230del p.P77Lfs*23 | Frame Shift Del (DEL) | VAF 49/322 reads (15%) | catalogued as rs1339990522; called by mutect2, pindel, varscan2
- FERMT2 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336467403, COSV58406568; called by muse, mutect2, varscan2
- GDF5 | c.157dup p.L53Pfs*41 | Frame Shift Ins (INS) | VAF 64/201 reads (32%) | catalogued as rs778834209; called by mutect2, varscan2
- GIN1 | c.368dup p.N123Kfs*24 | Frame Shift Ins (INS) | VAF 18/92 reads (20%) | catalogued as rs35774268; called by mutect2, pindel, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 53/165 reads (32%) | catalogued as rs771881138; called by mutect2, varscan2
- GLI2 | c.3842G>A p.R1281H (on ENST00000361492 / NM_001374353.1; = p.R1298H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs370407550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLIM4 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); catalogued as rs1179118459; called by muse, mutect2
- GPAT4 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs866666749, COSV67840516; called by muse, mutect2, varscan2
- GPR150 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101187391; called by muse, mutect2, varscan2
- GRB14 | c.612dup p.P205Sfs*10 | Frame Shift Ins (INS) | VAF 35/238 reads (15%) | catalogued as rs780357659; called by mutect2, varscan2
- HAS1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99708196; called by muse, mutect2
- HERC2 | c.13279C>T p.R4427* | Nonsense Mutation (SNP) | VAF 213/725 reads (29%) | catalogued as rs1224448657, COSV55330410; called by muse, mutect2, varscan2
- HNRNPL | c.1002del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as COSV99670288; called by pindel, varscan2
- HOXA7 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV54218477; called by muse, mutect2
- HSPA9 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 73/479 reads (15%) | catalogued as rs928003605; called by muse, mutect2, varscan2
- HTR3C | c.1324A>G p.I442V | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs372408664; called by muse, mutect2
- HYAL3 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 113/423 reads (27%) | catalogued as rs962456828; called by muse, mutect2, varscan2
- IFFO1 | c.1549C>T p.R517W (on ENST00000396840 / NM_001330324.2; = p.R520W on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762929628; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 72/284 reads (25%) | catalogued as rs760021495; called by mutect2, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 98/304 reads (32%) | catalogued as rs746629447; called by mutect2, varscan2
- ITGA11 | c.3377G>A p.R1126H | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs761739603, COSV59877586; called by muse, mutect2, varscan2
- ITGA5 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs949081104, COSV53217892; called by muse, mutect2, varscan2
- ITGAX | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs772509505, COSV51643584; called by muse, mutect2, varscan2
- ITPRID1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV60074174; called by muse, mutect2, varscan2
- JMY | c.857_858del p.C286Lfs*29 | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | catalogued as rs1291650256; called by pindel, varscan2
- KCNJ4 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1257702560, COSV57856386; called by muse, mutect2, varscan2
- KIAA0586 | c.3280A>G p.M1094V (on ENST00000619416 / NM_001244190.2; = p.M1033V on NM_014749.5) | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs773159825; called by muse, mutect2, varscan2
- KIAA1549L | c.4619C>T p.T1540I (on ENST00000321505; = p.T1837I on NM_012194.3) | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58597900; called by muse, mutect2, varscan2
- KIF7 | c.3424C>A p.L1142M | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV51541503; called by muse, mutect2, varscan2
- KLHL31 | c.312del p.D105Tfs*15 | Frame Shift Del (DEL) | VAF 49/305 reads (16%) | catalogued as rs1227078726; called by mutect2, pindel, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KMT2B | c.1656dup p.K553Qfs*46 | Frame Shift Ins (INS) | VAF 27/182 reads (15%) | catalogued as rs775294431; called by mutect2, varscan2
- KRT13 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 120/411 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55840952; called by muse, mutect2, varscan2
- KRT15 | c.99del p.S34Vfs*31 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | catalogued as COSV54178849; called by mutect2, pindel, varscan2
- KTN1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 11/198 reads (6%) | catalogued as rs1192477049, COSV101254930, COSV68023629; called by muse, mutect2
- LPCAT1 | c.772C>A p.L258M | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as rs866086697; called by muse, mutect2, varscan2
- LRATD1 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs867444164, COSV54472344; called by muse, mutect2, varscan2
- LRP1 | c.11990C>T p.S3997L | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs908851844, COSV54508232; called by muse, mutect2
- LRP2BP | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs550146373, COSV60750379; called by muse, mutect2, varscan2
- LRP4 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 113/412 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.49); catalogued as rs373683358; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRSAM1 | c.1490_1491del p.T497Rfs*44 | Frame Shift Del (DEL) | VAF 50/359 reads (14%) | catalogued as rs750319510; called by pindel, varscan2
- LZTS3 | c.1525G>A p.E509K (on ENST00000329152; = p.E463K on NM_001282533.2) | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1308499226, COSV53904340; called by muse, mutect2, varscan2
- MAPK12 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.268); catalogued as rs141322209; called by muse, mutect2, varscan2
- MARVELD3 | c.948dup p.Y317Vfs*22 | Frame Shift Ins (INS) | VAF 48/270 reads (18%) | catalogued as rs747980715; called by mutect2, varscan2
- MAST1 | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs1477286849, COSV52254077; called by muse, mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | catalogued as rs746267361; called by mutect2, varscan2
- MBOAT7 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as rs972203785; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 56/188 reads (30%) | catalogued as rs780635289; called by mutect2, varscan2
- MFSD6L | c.1583G>A p.C528Y | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs781134063, COSV61689081; called by muse, mutect2, varscan2
- MIA3 | c.1153del p.D385Tfs*19 | Frame Shift Del (DEL) | VAF 24/215 reads (11%) | catalogued as rs1242490454, COSV60514536; called by mutect2, pindel, varscan2
- MIOX | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 66/266 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs745768688; called by muse, mutect2, varscan2
- MMP21 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs762983237; called by muse, mutect2
- MPO | c.1596del p.F532Lfs*26 | Frame Shift Del (DEL) | VAF 90/355 reads (25%) | catalogued as rs1310078520; called by mutect2, pindel, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 58/333 reads (17%) | catalogued as rs757691558; called by mutect2, varscan2
- MST1R | c.3764C>T p.A1255V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs539807742, COSV56567637; called by muse, mutect2, varscan2
- MUS81 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs367647379; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 45/196 reads (23%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYH10 | c.4838C>T p.A1613V | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs746613898, COSV52610925; called by muse, mutect2, varscan2
- MYH15 | c.2590C>G p.L864V | Missense Mutation (SNP) | VAF 60/367 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56310842; called by muse, mutect2, varscan2
- MYH6 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62454745; called by muse, mutect2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 118/456 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- NCKIPSD | c.172-3del | Splice Region (DEL) | VAF 42/132 reads (32%) | catalogued as rs768132931; called by mutect2, varscan2
- NDC1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as rs1459859746; called by muse, mutect2, varscan2
- NECTIN1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs745849418; called by muse, mutect2, varscan2
- NEU2 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.02); catalogued as COSV52091852; called by muse, mutect2
- NLRC5 | c.1346del p.P449Lfs*17 | Frame Shift Del (DEL) | VAF 50/291 reads (17%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 23/150 reads (15%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOTCH2 | c.3359G>A p.C1120Y | Missense Mutation (SNP) | VAF 57/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56708984; called by muse, mutect2, varscan2
- NPFFR1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1404644791, COSV53335265; called by muse, mutect2, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- OLFM2 | c.932_934del p.N311del | In Frame Del (DEL) | VAF 44/202 reads (22%) | catalogued as rs770697718; called by pindel, varscan2
- OPA1 | c.2147C>T p.T716I (on ENST00000361510 / NM_130837.3; = p.T661I on NM_015560.3) | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV62482062; called by muse, mutect2
- OPN1LW | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 171/533 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV64064599; called by muse, mutect2, varscan2
- OSBP2 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.958); catalogued as rs1380678824, COSV60239989; called by muse, mutect2, varscan2
- OTOG | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 91/351 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs1442418425, COSV68037362; called by muse, mutect2, varscan2
- OTUD7B | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782482324; called by muse, mutect2
- OVOL2 | c.132dup p.E45Rfs*78 | Frame Shift Ins (INS) | VAF 16/85 reads (19%) | catalogued as rs890680601; called by mutect2, varscan2
- P2RY8 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1257073415, COSV67177339; called by muse, mutect2, varscan2
- PACSIN1 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs753017087; called by muse, mutect2, varscan2
- PAK4 | c.1542del p.Y515Tfs*10 | Frame Shift Del (DEL) | VAF 49/176 reads (28%) | catalogued as rs769136911; called by mutect2, pindel, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 64/322 reads (20%) | catalogued as CM011452; called by mutect2, varscan2
- PCDH10 | c.679dup p.Q227Pfs*19 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | catalogued as rs762465989; called by mutect2, varscan2
- PDK2 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs948527534; called by muse, mutect2, varscan2
- PGM5 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs201672908, COSV67168317; called by muse, mutect2, varscan2
- PIF1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1360369714; called by muse, mutect2, varscan2
- PIGU | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs376729351; called by muse, mutect2, varscan2
- PIH1D1 | c.743del p.G248Afs*8 | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | catalogued as rs1274833333; called by mutect2, pindel, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 34/135 reads (25%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PNMA8A | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.674); catalogued as rs565739284, COSV58137993; called by muse, mutect2, varscan2
- PNMT | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1398994932; called by muse, mutect2, varscan2
- POLE | c.6233G>A p.R2078Q | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs745721448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121L12 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.021); catalogued as COSV68692529; called by muse, mutect2, varscan2
- PPIAL4D | c.377A>C p.H126P | Missense Mutation (SNP) | VAF 113/660 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.624); catalogued as rs1188368393; called by muse, mutect2, varscan2
- PPP1R13B | c.1531del p.Q511Sfs*39 | Frame Shift Del (DEL) | VAF 49/194 reads (25%) | catalogued as rs758922105; called by mutect2, varscan2
- PRICKLE1 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 142/525 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs748173327, COSV58204493; called by muse, mutect2, varscan2
- PRMT3 | c.1438T>C p.W480R | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58175957; called by muse, mutect2, varscan2
- PRPF8 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 98/359 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as rs988863886; called by muse, mutect2, varscan2
- PRR23B | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 102/378 reads (27%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.992); catalogued as COSV61493319; called by muse, mutect2, varscan2
- PTEN | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 93/399 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD115952, CM020754, CM110121, COSV64288552, COSV64296626; called by muse, mutect2, varscan2
- QSOX1 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs769299023, COSV62581061; called by muse, mutect2, varscan2
- RAB11B | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV60085564; called by muse, mutect2
- RINT1 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs753489260, COSV57557068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 58/170 reads (34%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RNPEPL1 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 104/334 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs753729782; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 25/206 reads (12%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL26 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV53447178; called by muse, mutect2, varscan2
- RPS8 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs767419318, COSV63234613; called by muse, mutect2, varscan2
- RTL5 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV101029814; called by muse, mutect2, varscan2
- SALL3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1433758208; called by muse, mutect2, varscan2
- SATB1 | c.1943G>A p.R648Q | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs865844797, COSV58669636; called by muse, mutect2, varscan2
- SBNO2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs972597562; called by muse, mutect2, varscan2
- SEC16A | c.6197del p.P2066Qfs*76 | Frame Shift Del (DEL) | VAF 44/148 reads (30%) | catalogued as COSV99256980; called by mutect2, pindel
- SHROOM3 | c.2848dup p.A950Gfs*43 | Frame Shift Ins (INS) | VAF 13/55 reads (24%) | catalogued as rs863225433; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SIPA1L2 | c.4583C>T p.T1528M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs376213911; called by muse, mutect2, varscan2
- SLC12A4 | c.2479G>A p.V827M | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs750182082, COSV50452583; called by muse, mutect2
- SLC22A6 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs367801309; called by muse, mutect2, varscan2
- SLC35B2 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.272); catalogued as COSV51491945; called by muse, mutect2, varscan2
- SLC8A2 | c.71del p.P24Qfs*172 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs1568448382; called by mutect2, pindel, varscan2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 20/182 reads (11%) | catalogued as rs774532876; called by mutect2, varscan2
- SMC1A | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 129/440 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59130546; called by muse, mutect2, varscan2
- SMIM9 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1229466926; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 26/208 reads (13%) | catalogued as rs768873484; called by mutect2, varscan2
- SP140 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV59446219; called by muse, mutect2, varscan2
- SP6 | c.1080dup p.G361Rfs*78 | Frame Shift Ins (INS) | VAF 15/112 reads (13%) | catalogued as rs768829645; called by mutect2, pindel
- SPAG16 | c.1505T>C p.L502P | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs745726263; called by muse, mutect2, varscan2
- SPATA20 | c.258G>T p.W86C (on ENST00000356488 / NM_001258372.1; = p.W102C on NM_022827.4) | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50070027; called by muse, mutect2, varscan2
- SPINK5 | c.2495C>T p.T832I | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.341); catalogued as COSV56258246; called by muse, mutect2, varscan2
- SPINK8 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs199811709; called by muse, mutect2, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 42/186 reads (23%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPRED3 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs772047594; called by muse, varscan2
- SPSB3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51905027; called by muse, mutect2, varscan2
- SRARP | c.263del p.N88Tfs*5 | Frame Shift Del (DEL) | VAF 22/160 reads (14%) | catalogued as COSV61497803; called by mutect2, pindel, varscan2
- STIP1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1390687662, COSV54184284; called by muse, mutect2, varscan2
- STOML2 | c.427_428del p.L143Gfs*23 | Frame Shift Del (DEL) | VAF 68/258 reads (26%) | catalogued as rs1564008198; called by pindel, varscan2
- SULT1B1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs370321903; called by muse, mutect2, varscan2
- SYT3 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58895472; called by muse, mutect2
- SZT2 | c.8315C>T p.T2772M (on ENST00000634258 / NM_001365999.1; = p.T2715M on NM_015284.4) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1174812322, COSV65173499; called by muse, mutect2, varscan2
- SZT2 | c.9842G>A p.R3281H (on ENST00000634258 / NM_001365999.1; = p.R3224H on NM_015284.4) | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs940069079, COSV100981376; called by muse, mutect2, varscan2
- TBC1D10C | c.1281del p.I428Sfs*126 | Frame Shift Del (DEL) | VAF 53/170 reads (31%) | catalogued as rs756043635; called by mutect2, pindel, varscan2
- TBL1X | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 18/290 reads (6%) | catalogued as COSV99482669, COSV99482670; called by muse, mutect2
- TBX2 | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs748195981, COSV53600525; called by muse, mutect2, varscan2
- TCF20 | c.3848G>A p.R1283H | Missense Mutation (SNP) | VAF 89/288 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as rs750743110; called by muse, mutect2, varscan2
- TKT | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781993830; called by muse, mutect2, varscan2
- TLK2 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs750314324; called by muse, mutect2, varscan2
- TLN1 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1405406696; called by muse, mutect2, varscan2
- TLR7 | c.2885C>T p.A962V | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.035); catalogued as COSV101028131; called by muse, mutect2
- TMC2 | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 105/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200272296, COSV100727628; called by muse, mutect2, varscan2
- TMCC2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs770054045; called by muse, mutect2, varscan2
- TMCC2 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100319488; called by muse, mutect2, varscan2
- TMEM168 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57180324; called by muse, mutect2, varscan2
- TMEM54 | c.268del p.L90Cfs*17 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | catalogued as rs1307577775; called by mutect2, pindel, varscan2
- TMOD2 | c.170A>G p.Q57R | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as rs767505992; called by muse, mutect2, varscan2
- TNIK | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs746542637, COSV104371603; called by muse, mutect2, varscan2
- TNK2 | c.1522del p.Q508Sfs*3 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs754147115; called by mutect2, pindel
- TRIM58 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.165); catalogued as rs371240676, COSV100825159; called by muse, mutect2, varscan2
- TSC2 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs876658578, COSV54758369; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TSEN34 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 110/366 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs1227908081, COSV99824558; called by muse, varscan2
- TXNDC11 | c.2591G>A p.R864Q (on ENST00000356957 / NM_001303447.2; = p.R837Q on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/256 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs754911296, COSV51597925; called by muse, mutect2, varscan2
- TYW1B | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782414363; called by muse, mutect2, varscan2
- UHMK1 | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as rs375343785; called by muse, mutect2, varscan2
- UHRF1 | c.1082C>A p.P361H (on ENST00000612630 / NM_001290050.1; = p.P374H on NM_013282.4) | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53573519; called by muse, mutect2, varscan2
- UNC13C | c.3127del p.T1043Lfs*10 | Frame Shift Del (DEL) | VAF 44/236 reads (19%) | catalogued as rs749125502, COSV52929254; called by mutect2, varscan2
- USP36 | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs559790137, COSV61752549; called by muse, varscan2
- VEGFC | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.043); catalogued as rs1322817809, COSV54601939; called by muse, mutect2, varscan2
- VRTN | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs776042484, COSV56441755; called by muse, mutect2, varscan2
- VSTM4 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs370616319, COSV53676968; called by muse, varscan2
- VWC2L | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 74/355 reads (21%) | catalogued as rs1473508513; called by muse, mutect2, varscan2
- WASF3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100099009; called by muse, mutect2, varscan2
- WDR43 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1411224259, COSV101332957; called by muse, mutect2, varscan2
- WDR83 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs909585373; called by muse, mutect2
- WNT2 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199687912, COSV55413135; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 33/130 reads (25%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFHX3 | c.2699C>T p.A900V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs1303584175; called by muse, mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 46/168 reads (27%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF407 | c.1378T>C p.Y460H | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs976889493; called by muse, mutect2
- ZNF407 | c.4300G>A p.A1434T | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1327381494; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 52/160 reads (33%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF668 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.057); catalogued as rs1195374886; called by muse, mutect2, varscan2
- ZNF71 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100045399; called by muse, mutect2
- ZNFX1 | c.1257del p.M420Cfs*7 | Frame Shift Del (DEL) | VAF 75/270 reads (28%) | catalogued as rs1203012454; called by mutect2, pindel, varscan2
- ZSWIM7 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as rs1267671688; called by muse, mutect2, varscan2
- ABCA9 | c.1877T>C p.L626P | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC231657.3 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ACHE | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACOT2 | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ACSM6 | c.994A>G p.S332G | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- ACSS1 | c.1268A>G p.E423G | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ACTA1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ADAM19 | c.2063del p.G688Afs*17 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- ADCK2 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADRB2 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFF2 | c.2575G>T p.E859* | Nonsense Mutation (SNP) | VAF 39/149 reads (26%) | called by muse, mutect2, varscan2
- AGBL4 | c.1192T>C p.Y398H | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMBP | c.78dup p.D27Rfs*66 | Frame Shift Ins (INS) | VAF 71/234 reads (30%) | called by mutect2, pindel, varscan2
- ANK3 | c.6587C>A p.P2196H | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD11 | c.3751A>G p.K1251E | Missense Mutation (SNP) | VAF 94/470 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ANKRD26 | c.3805C>T p.Q1269* | Nonsense Mutation (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1753dup p.S585Ffs*29 | Frame Shift Ins (INS) | VAF 13/165 reads (8%) | called by mutect2, pindel
- ANO6 | c.1315_1317del p.E439del | In Frame Del (DEL) | VAF 61/282 reads (22%) | called by pindel, varscan2
- AQP3 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- ARHGAP32 | c.4832C>T p.A1611V (on ENST00000310343 / NM_001378025.1; = p.A1262V on NM_014715.4) | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.022); called by muse, mutect2
- ARHGAP5 | c.2676dup p.E893* | Frame Shift Ins (INS) | VAF 60/190 reads (32%) | called by mutect2, varscan2
- ARHGEF4 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ARID1A | c.4403del p.P1468Lfs*13 | Frame Shift Del (DEL) | VAF 106/388 reads (27%) | called by mutect2, pindel, varscan2
- ARID1A | c.6254T>C p.L2085P | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1B | c.2777A>C p.N926T | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ATP2A1 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 73/398 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2C1 | c.2194A>G p.M732V | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATRX | c.1074dup p.L359Tfs*3 | Frame Shift Ins (INS) | VAF 32/179 reads (18%) | called by mutect2, varscan2
- BAZ2A | c.3600G>A p.M1200I | Missense Mutation (SNP) | VAF 115/419 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCHE | c.626del p.N209Ifs*2 | Frame Shift Del (DEL) | VAF 60/181 reads (33%) | called by mutect2, pindel, varscan2
- BCOR | c.2399G>A p.S800N | Missense Mutation (SNP) | VAF 194/731 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- BICRA | c.3222del p.T1075Rfs*71 | Frame Shift Del (DEL) | VAF 37/212 reads (17%) | called by mutect2, pindel, varscan2
- BPHL | c.674G>A p.C225Y | Missense Mutation (SNP) | VAF 61/220 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRSK1 | c.1748C>T p.T583M | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, varscan2
- C12orf40 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CABP7 | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- CACNA1B | c.2362T>C p.Y788H | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CACNA1E | c.5245G>A p.A1749T | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CACNB3 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAGE1 | c.2271T>G p.N757K (on ENST00000512086; = p.N621K on NM_205864.3) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CBL | c.626T>C p.L209P | Missense Mutation (SNP) | VAF 93/372 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBR1 | c.770del p.L257Cfs*38 | Frame Shift Del (DEL) | VAF 59/200 reads (30%) | called by mutect2, pindel, varscan2
- CBWD5 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CBX3 | c.31del p.M11Wfs*26 | Frame Shift Del (DEL) | VAF 30/150 reads (20%) | called by mutect2, pindel
- CCBE1 | c.791A>G p.K264R | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CCDC180 | c.2668A>G p.R890G | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCIN | c.1595del p.G532Vfs*46 | Frame Shift Del (DEL) | VAF 143/512 reads (28%) | called by mutect2, pindel, varscan2
- CD47 | c.401-2A>G p.X134_splice | Splice Site (SNP) | VAF 32/98 reads (33%) | called by muse, mutect2, varscan2
- CD81 | c.173_175del p.F58del | In Frame Del (DEL) | VAF 78/487 reads (16%) | called by mutect2, pindel, varscan2
- CDH8 | c.1047del p.K349Nfs*5 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | called by mutect2, pindel
- CDK5RAP2 | c.3814C>A p.Q1272K | Missense Mutation (SNP) | VAF 63/483 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CFAP46 | c.5905C>T p.Q1969* | Nonsense Mutation (SNP) | VAF 50/266 reads (19%) | called by muse, mutect2, varscan2
- CFAP65 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHD4 | c.3471_3473del p.M1157del (on ENST00000357008 / NM_001363606.2; = p.M1170del on NM_001273.5) | In Frame Del (DEL) | VAF 41/267 reads (15%) | called by mutect2, pindel, varscan2
- CHD6 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CHMP5 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLASP1 | c.2368G>C p.A790P | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- CLDN6 | c.567del p.S190Pfs*70 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel
- CLEC4M | c.844A>G p.M282V | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN2 | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CNTN5 | c.2853G>T p.R951S | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- COQ10A | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CPZ | c.1637del p.P546Qfs*26 (on ENST00000360986 / NM_001014447.3; = p.P535Qfs*26 on NM_003652.3) | Frame Shift Del (DEL) | VAF 102/320 reads (32%) | called by mutect2, pindel, varscan2
- CRYBG3 | c.1716del p.F572Lfs*12 | Frame Shift Del (DEL) | VAF 67/200 reads (34%) | called by mutect2, pindel, varscan2
- DAPK1 | c.3822del p.Y1275Tfs*31 | Frame Shift Del (DEL) | VAF 36/108 reads (33%) | called by mutect2, varscan2
- DCAF13 | c.629T>C p.F210S | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCHS1 | c.5471G>T p.R1824M | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DDX55 | c.1171del p.L391Cfs*4 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- DGKI | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHRS7B | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 69/444 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- DIS3L | c.293G>T p.R98I (on ENST00000319212 / NM_001143688.3; = p.R15I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DMRTB1 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH6 | c.3982A>G p.M1328V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- DNAJC2 | c.590del p.N197Mfs*8 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, varscan2
- DOCK11 | c.4376C>T p.S1459L | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- DOCK5 | c.4244G>T p.G1415V | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DST | c.8705C>T p.T2902I | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DUS4L | c.887G>A p.R296K | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DUSP6 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DYNC1H1 | c.8145dup p.T2716Hfs*83 | Frame Shift Ins (INS) | VAF 160/642 reads (25%) | called by mutect2, pindel, varscan2
- EIF2A | c.1609del p.I537Sfs*4 | Frame Shift Del (DEL) | VAF 58/178 reads (33%) | called by mutect2, pindel, varscan2
- EML6 | c.4845del p.E1616Rfs*10 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by mutect2, pindel
- ENO4 | c.691C>T p.P231S (on ENST00000622726; = p.P230S on NM_001242699.2) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- EP300 | c.4722del p.N1575Mfs*23 | Frame Shift Del (DEL) | VAF 62/221 reads (28%) | called by mutect2, pindel, varscan2
- ERC1 | c.2560G>A p.A854T (on ENST00000360905 / NM_178040.4; = p.A826T on NM_178039.4) | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ERN1 | c.2503C>A p.L835I | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EXOSC8 | c.809_812del p.I270Rfs*3 | Frame Shift Del (DEL) | VAF 31/123 reads (25%) | called by mutect2, pindel, varscan2
- FADS1 | c.116dup p.S40Efs*59 | Frame Shift Ins (INS) | VAF 36/148 reads (24%) | called by mutect2, pindel, varscan2
- FAM53B | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FASTKD5 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 80/303 reads (26%) | called by muse, mutect2, varscan2
- FHOD3 | c.2918T>C p.L973P (on ENST00000359247 / NM_001281739.3; = p.L990P on NM_025135.5) | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FIGNL2 | c.495del p.Y166Tfs*66 | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | called by mutect2, pindel, varscan2
- FLVCR2 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 203/666 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- FNIP1 | c.2196del p.K732Nfs*23 | Frame Shift Del (DEL) | VAF 66/262 reads (25%) | called by mutect2, varscan2
- FOXP1 | c.1174_1175del p.S392Qfs*68 | Frame Shift Del (DEL) | VAF 48/313 reads (15%) | called by pindel, varscan2
- G3BP2 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- GAB4 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); called by muse, varscan2
- GABRR1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- GDNF | c.377A>T p.N126I | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GPR108 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GPR149 | c.1744del p.I582* | Frame Shift Del (DEL) | VAF 19/171 reads (11%) | called by mutect2, pindel, varscan2
- GPRIN2 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- GREB1 | c.3460del p.Q1154Rfs*96 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | called by mutect2, pindel, varscan2
- GSE1 | c.2474_2475del p.R825Kfs*27 | Frame Shift Del (DEL) | VAF 86/412 reads (21%) | called by pindel, varscan2
- GSG1 | c.385T>C p.W129R | Missense Mutation (SNP) | VAF 78/443 reads (18%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAAO | c.441-7C>A | Splice Region (SNP) | VAF 40/202 reads (20%) | called by muse, mutect2, varscan2
- HAUS1 | c.787-1G>T p.X263_splice | Splice Site (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- HECTD4 | c.10468G>A p.A3490T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.011); called by muse, mutect2
- HEPH | c.3243del p.A1082Qfs*12 (on ENST00000343002; = p.A815Qfs*12 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 47/256 reads (18%) | called by mutect2, pindel, varscan2
- HEXA | c.1341G>T p.E447D | Missense Mutation (SNP) | VAF 19/377 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- HHIPL1 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSP90AA1 | c.1696del p.T566Qfs*10 | Frame Shift Del (DEL) | VAF 114/385 reads (30%) | called by mutect2, pindel, varscan2
- HSPA14 | c.858T>G p.Y286* | Nonsense Mutation (SNP) | VAF 21/146 reads (14%) | called by muse, mutect2, varscan2
- IFT140 | c.482del p.P161Lfs*14 | Frame Shift Del (DEL) | VAF 37/139 reads (27%) | called by mutect2, pindel, varscan2
- IGSF5 | c.140del p.N47Mfs*5 | Frame Shift Del (DEL) | VAF 44/184 reads (24%) | called by mutect2, pindel
- IL17RC | c.914G>A p.G305D (on ENST00000295981 / NM_153461.4; = p.G219D on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/366 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- INTS9 | c.1742T>C p.L581P | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRS2 | c.1723A>G p.T575A | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ISL1 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITGAL | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- KCNJ11 | c.634A>G p.S212G | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCNN1 | c.1593del p.C532Afs*48 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel
- KCNQ2 | c.477del p.R160Gfs*11 | Frame Shift Del (DEL) | VAF 55/308 reads (18%) | called by mutect2, pindel, varscan2
- KIAA1958 | c.1719G>T p.Q573H | Missense Mutation (SNP) | VAF 18/556 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); called by muse, mutect2
- KLB | c.2836A>G p.T946A | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- KLHL10 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KLHL9 | c.93_96del p.H32Vfs*13 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- KLK11 | c.201G>A p.W67* (on ENST00000594768 / NM_144947.3; = p.W35* on NM_006853.3) | Nonsense Mutation (SNP) | VAF 37/103 reads (36%) | called by muse, mutect2, varscan2
- KMT2B | c.6413del p.P2138Rfs*15 | Frame Shift Del (DEL) | VAF 21/173 reads (12%) | called by mutect2, varscan2
- LAMC2 | c.1708T>G p.C570G | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGALS1 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LPA | c.5017G>T p.G1673C | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- LPIN3 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- LRFN2 | c.2320del p.A774Pfs*11 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | called by mutect2, pindel
- LRIT1 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRR1 | c.1066dup p.I356Nfs*33 | Frame Shift Ins (INS) | VAF 74/278 reads (27%) | called by mutect2, pindel, varscan2
- LRRC8A | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 111/434 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LY75 | c.3062del p.K1021Rfs*2 | Frame Shift Del (DEL) | VAF 81/328 reads (25%) | called by mutect2, pindel, varscan2
- MAMDC4 | c.2820+8C>T | Splice Region (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- MANEA | c.831del p.K277Nfs*6 | Frame Shift Del (DEL) | VAF 61/230 reads (27%) | called by mutect2, pindel, varscan2
- MANEAL | c.1243_1245del p.K415del (on ENST00000373045 / NM_001113482.1; = p.K193del on NM_152496.2) | In Frame Del (DEL) | VAF 126/458 reads (28%) | called by mutect2, pindel, varscan2
- MBD1 | c.1202del p.P401Hfs*21 (on ENST00000269468 / NM_001323950.1; = p.P345Hfs*21 on NM_002384.2) | Frame Shift Del (DEL) | VAF 83/351 reads (24%) | called by mutect2, pindel, varscan2
- MBD3 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 121/437 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MBD6 | c.2086_2101del p.X696_splice | Splice Site (DEL) | VAF 40/268 reads (15%) | called by mutect2, pindel
- MCHR2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 36/405 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.411); called by muse, mutect2
- MDN1 | c.11326G>T p.G3776C | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MLPH | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 82/414 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, varscan2
- MME | c.594dup p.V199Sfs*4 | Frame Shift Ins (INS) | VAF 29/244 reads (12%) | called by mutect2, pindel, varscan2
- MNT | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MSL2 | c.1490G>A p.G497D | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7A | c.5657C>A p.P1886H | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NACC2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NECTIN4 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 135/482 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by mutect2, varscan2
- NEIL1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 107/383 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NEK1 | c.1569del p.Q525Sfs*2 | Frame Shift Del (DEL) | VAF 26/117 reads (22%) | called by mutect2, pindel
- NETO2 | c.1127del p.K376Rfs*28 | Frame Shift Del (DEL) | VAF 49/308 reads (16%) | called by mutect2, pindel, varscan2
- NF1 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 67/222 reads (30%) | called by muse, mutect2, varscan2
- NFAT5 | c.634del p.V212Sfs*52 | Frame Shift Del (DEL) | VAF 89/298 reads (30%) | called by mutect2, pindel, varscan2
- NID2 | c.3154del p.L1052Cfs*50 | Frame Shift Del (DEL) | VAF 41/263 reads (16%) | called by mutect2, pindel, varscan2
- NOBOX | c.1488del p.C497Vfs*53 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.3461G>A p.C1154Y | Missense Mutation (SNP) | VAF 66/378 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NT5C1B | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NYNRIN | c.2498C>T p.T833I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10G7 | c.908del p.N303Mfs*11 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | called by mutect2, pindel, varscan2
- OSMR | c.2699del p.N900Tfs*3 | Frame Shift Del (DEL) | VAF 109/387 reads (28%) | called by mutect2, pindel, varscan2
- P2RY14 | c.738dup p.V247Cfs*57 | Frame Shift Ins (INS) | VAF 60/364 reads (16%) | called by mutect2, pindel, varscan2
- PAX7 | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- PCLO | c.10550C>T p.A3517V | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PDCL3 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, varscan2
- PDS5A | c.3974del p.K1325Rfs*46 | Frame Shift Del (DEL) | VAF 34/174 reads (20%) | called by mutect2, pindel
- PHEX | c.941G>T p.W314L | Missense Mutation (SNP) | VAF 109/426 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PHF1 | c.16del p.R6Gfs*2 | Frame Shift Del (DEL) | VAF 27/151 reads (18%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- PLCXD1 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- PLIN4 | c.1681del p.A561Qfs*13 (on ENST00000301286; = p.A576Qfs*13 on NM_001367868.2) | Frame Shift Del (DEL) | VAF 52/291 reads (18%) | called by mutect2, pindel, varscan2
- POPDC3 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PPP1R13B | c.2397del p.E800Nfs*71 | Frame Shift Del (DEL) | VAF 28/130 reads (22%) | called by mutect2, pindel, varscan2
- PRDM1 | c.1251del p.Y418Tfs*3 | Frame Shift Del (DEL) | VAF 45/165 reads (27%) | called by mutect2, pindel, varscan2
- PRF1 | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- PRG2 | c.292G>C p.V98L | Missense Mutation (SNP) | VAF 63/288 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRICKLE3 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PRKCZ | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PRMT1 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PROC | c.341G>A p.G114D | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- PRPH | c.1410C>A p.Y470* | Nonsense Mutation (SNP) | VAF 66/255 reads (26%) | called by muse, mutect2, varscan2
- PSMA8 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PSMD1 | c.372del p.K124Nfs*11 | Frame Shift Del (DEL) | VAF 48/192 reads (25%) | called by mutect2, varscan2
- PTBP3 | c.1147G>T p.G383C | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTCHD3 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- PTN | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPN23 | c.4049T>C p.L1350P | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PXDN | c.3217G>T p.G1073C | Missense Mutation (SNP) | VAF 182/589 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QSER1 | c.773T>C p.V258A (on ENST00000399302; = p.V387A on NM_001076786.3) | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB24 | c.127del p.A43Pfs*7 | Frame Shift Del (DEL) | VAF 62/177 reads (35%) | called by mutect2, pindel, varscan2
- RANBP2 | c.8201C>T p.T2734I | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RASL11B | c.142+2T>C p.X48_splice | Splice Site (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- RBM19 | c.1498A>G p.K500E | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RGP1 | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- RIN3 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2
- RLF | c.3768T>A p.D1256E | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RNF112 | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RNF34 | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 26/203 reads (13%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS6KA3 | c.2203del p.I735Sfs*66 | Frame Shift Del (DEL) | VAF 79/527 reads (15%) | called by mutect2, pindel, varscan2
- RXRB | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAC3D1 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SAE1 | c.446del p.N149Ifs*21 | Frame Shift Del (DEL) | VAF 30/224 reads (13%) | called by pindel, varscan2
- SAMD4A | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCLY | c.478dup p.L160Pfs*48 (on ENST00000651534; = p.L152Pfs*48 on NM_016510.7) | Frame Shift Ins (INS) | VAF 19/117 reads (16%) | called by mutect2, pindel
- SDHAF3 | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- SELENOS | c.309del p.K103Nfs*2 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- SEMA5A | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 44/211 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- SEMA5A | c.2618C>A p.P873Q | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3BP4 | c.101G>T p.S34I | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SKOR2 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 118/363 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC23A1 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SLC29A3 | c.202T>C p.W68R | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SLC2A14 | c.79del p.S27Lfs*23 | Frame Shift Del (DEL) | VAF 41/147 reads (28%) | called by mutect2, pindel, varscan2
- SLC39A6 | c.1873G>T p.G625C | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A14 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC8B1 | c.1221del p.F407Lfs*21 | Frame Shift Del (DEL) | VAF 30/171 reads (18%) | called by mutect2, pindel, varscan2
- SMAD5 | c.1133G>A p.C378Y | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- SMARCA1 | c.2031del p.F677Lfs*8 | Frame Shift Del (DEL) | VAF 40/190 reads (21%) | called by mutect2, pindel, varscan2
- SMARCC1 | c.1315dup p.E439Gfs*3 | Frame Shift Ins (INS) | VAF 34/234 reads (15%) | called by mutect2, pindel, varscan2
- SMYD5 | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.939); called by muse, mutect2
- SNED1 | c.2102del p.P701Rfs*4 | Frame Shift Del (DEL) | VAF 46/154 reads (30%) | called by mutect2, pindel, varscan2
- SORBS1 | c.2798del p.N933Tfs*59 (on ENST00000361941 / NM_001034954.2; = p.N583Tfs*97 on NM_006434.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- SOX17 | c.363dup p.E122Rfs*40 | Frame Shift Ins (INS) | VAF 36/118 reads (31%) | called by mutect2, pindel, varscan2
- SOX8 | c.1116del p.A373Pfs*71 | Frame Shift Del (DEL) | VAF 39/179 reads (22%) | called by mutect2, pindel, varscan2
- SOX9 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SP5 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 63/359 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- SPATA32 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 78/587 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- SPEG | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- SPPL2A | c.1463del p.K488Sfs*10 | Frame Shift Del (DEL) | VAF 20/137 reads (15%) | called by mutect2, pindel, varscan2
- SPTA1 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 116/422 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SRRM1 | c.2636A>G p.N879S | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SSTR4 | c.121del p.D41Tfs*31 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, varscan2
- STAC2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- STAM2 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- SUFU | c.846del p.E283Rfs*30 | Frame Shift Del (DEL) | VAF 56/240 reads (23%) | called by mutect2, pindel, varscan2
- SYNE1 | c.4964C>T p.A1655V (on ENST00000367255 / NM_182961.4; = p.A1662V on NM_033071.3) | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SYNM | c.914G>A p.S305N | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TACC3 | c.593C>G p.A198G | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D14 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TDRD1 | c.203dup p.L68Ffs*4 | Frame Shift Ins (INS) | VAF 48/175 reads (27%) | called by mutect2, pindel, varscan2
- TET3 | c.3742C>T p.P1248S | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.316); called by muse, mutect2
- TFF2 | c.382C>A p.H128N | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TGFB3 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 130/439 reads (30%) | called by muse, mutect2, varscan2
- THBS1 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- TIMELESS | c.332dup p.L111Ffs*17 | Frame Shift Ins (INS) | VAF 63/276 reads (23%) | called by mutect2, pindel, varscan2
- TMPO | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 49/292 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TMPRSS7 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- TNFAIP2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TNN | c.234_235insG p.R79Efs*49 | Frame Shift Ins (INS) | VAF 28/183 reads (15%) | called by mutect2, pindel*, varscan2
- TNN | c.2426C>T p.T809I | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- TNRC18 | c.4962del p.K1655Nfs*12 | Frame Shift Del (DEL) | VAF 77/329 reads (23%) | called by mutect2, pindel, varscan2
- TOMM20 | c.100T>C p.F34L | Missense Mutation (SNP) | VAF 89/276 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TPCN2 | c.1903_1905del p.N635del | In Frame Del (DEL) | VAF 40/190 reads (21%) | called by pindel, varscan2
- TPGS2 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2
- TRAPPC12 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 33/269 reads (12%) | called by muse, mutect2, varscan2
- TRIB1 | c.496dup p.D166Gfs*44 | Frame Shift Ins (INS) | VAF 44/343 reads (13%) | called by mutect2, pindel, varscan2
- TRIM35 | c.1343G>A p.C448Y | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1867del p.M623Wfs*6 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | called by mutect2, pindel, varscan2
- TTC13 | c.783A>G p.I261M | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TXNL4B | c.378dup p.K127Efs*9 | Frame Shift Ins (INS) | VAF 14/148 reads (9%) | called by mutect2, pindel
- UBR4 | c.8406del p.M2803Cfs*16 | Frame Shift Del (DEL) | VAF 36/244 reads (15%) | called by mutect2, pindel, varscan2
- UBR5 | c.639T>A p.N213K | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- UNC80 | c.8863C>T p.P2955S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- USP51 | c.476G>T p.R159M | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- USP6 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 142/463 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- VIL1 | c.1858del p.R620Gfs*33 | Frame Shift Del (DEL) | VAF 47/141 reads (33%) | called by mutect2, pindel, varscan2
- VPS4A | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- VRK3 | c.1218-2A>G p.X406_splice | Splice Site (SNP) | VAF 74/257 reads (29%) | called by muse, mutect2, varscan2
- VTN | c.1225_1227del p.E409del | In Frame Del (DEL) | VAF 39/240 reads (16%) | called by pindel, varscan2
- VWA5A | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- WASH6P | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 44/834 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- WDR24 | c.1574G>A p.S525N (on ENST00000248142; = p.S395N on NM_032259.4) | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2
- XIRP1 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- XIRP2 | c.7940del p.N2647Ifs*6 (on ENST00000628543; = p.N2822Ifs*6 on NM_152381.6) | Frame Shift Del (DEL) | VAF 56/272 reads (21%) | called by mutect2, varscan2
- ZBTB16 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 63/387 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ZFAND4 | c.1871dup p.L624Ffs*12 | Frame Shift Ins (INS) | VAF 18/106 reads (17%) | called by mutect2, varscan2
- ZFX | c.2255G>A p.C752Y | Missense Mutation (SNP) | VAF 137/484 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZMPSTE24 | c.791G>A p.S264N | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF234 | c.1480A>C p.S494R | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); called by muse, mutect2
- ZNF439 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF648 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ZNF829 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- ZNF83 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AC011462.1 | c.687C>T p.Y229= | Silent (SNP) | VAF 19/342 reads (6%) | catalogued as rs575806482, COSV54196629; called by muse, mutect2
- ACACB | c.6369G>A p.Q2123= | Silent (SNP) | VAF 50/179 reads (28%) | catalogued as rs1341282038; called by muse, mutect2, varscan2
- ACAP3 | c.1617G>A p.L539= | Silent (SNP) | VAF 49/233 reads (21%) | called by muse, mutect2, varscan2
- ACSBG2 | c.1479C>T p.H493= | Silent (SNP) | VAF 87/298 reads (29%) | catalogued as rs746910468; called by muse, mutect2, varscan2
- ADRA1B | c.1128C>A p.R376= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as rs1561612939, COSV100140557; called by muse, mutect2, varscan2
- AGXT | c.27C>A p.T9= | Silent (SNP) | VAF 94/265 reads (35%) | catalogued as rs180177188, COSV56754072; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- ALCAM | c.1645C>T p.L549= | Silent (SNP) | VAF 89/269 reads (33%) | called by muse, mutect2, varscan2
- ALDH1B1 | c.168G>A p.T56= | Silent (SNP) | VAF 72/223 reads (32%) | catalogued as rs768474170, COSV100890926; called by muse, mutect2, varscan2
- ANGEL2 | c.333C>T p.Y111= | Silent (SNP) | VAF 51/252 reads (20%) | catalogued as rs760701370, COSV64738549; called by muse, mutect2, varscan2
- ANTKMT | c.378C>T p.S126= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as rs1490499605; called by muse, mutect2, varscan2
- ARHGEF39 | c.120G>A p.Q40= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs779989203; called by muse, mutect2, varscan2
- ARHGEF40 | c.3060C>T p.G1020= | Silent (SNP) | VAF 49/429 reads (11%) | catalogued as rs1387367463; called by muse, mutect2, varscan2
- ARID1B | c.6174A>G p.G2058= | Silent (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- ASGR1 | c.675C>T p.D225= | Silent (SNP) | VAF 74/273 reads (27%) | catalogued as COSV99352552; called by muse, mutect2, varscan2
- ATN1 | c.1932G>A p.P644= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as rs139183408; called by muse, mutect2, varscan2
- ATP11A | c.2715G>T p.G905= | Silent (SNP) | VAF 78/284 reads (27%) | called by muse, mutect2, varscan2
- BACE1 | c.429C>T p.T143= | Silent (SNP) | VAF 58/207 reads (28%) | catalogued as rs140380263; called by muse, mutect2, varscan2
- BCHE | c.60C>T p.C20= | Silent (SNP) | VAF 64/209 reads (31%) | called by muse, mutect2, varscan2
- BICD2 | c.84G>A p.R28= | Silent (SNP) | VAF 34/276 reads (12%) | catalogued as rs1373796052; called by muse, mutect2, varscan2
- C2CD4C | c.417C>A p.P139= | Silent (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- C3 | c.426C>T p.G142= | Silent (SNP) | VAF 20/606 reads (3%) | catalogued as rs979178290; called by muse, mutect2
- CACNA1D | c.4269T>C p.P1423= (on ENST00000350061 / NM_001128840.3; = p.P1443= on NM_000720.4) | Silent (SNP) | VAF 104/362 reads (29%) | called by muse, mutect2, varscan2
- CAND2 | c.306G>A p.L102= | Silent (SNP) | VAF 51/185 reads (28%) | called by muse, mutect2, varscan2
- CARMIL1 | c.1977C>T p.N659= | Silent (SNP) | VAF 90/334 reads (27%) | catalogued as rs1368491534; called by muse, mutect2, varscan2
- CASZ1 | c.4860G>A p.L1620= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs1357587095; called by muse, mutect2, varscan2
- CCER1 | c.705G>A p.A235= | Silent (SNP) | VAF 59/199 reads (30%) | catalogued as COSV100727138; called by muse, mutect2, varscan2
- CCNL2 | c.1425G>A p.E475= | Silent (SNP) | VAF 32/255 reads (13%) | catalogued as COSV68767140; called by muse, mutect2, varscan2
- CDH12 | c.945T>C p.N315= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as rs753988533; called by muse, varscan2
- CDKN1C | c.276C>T p.R92= | Silent (SNP) | VAF 72/330 reads (22%) | called by muse, mutect2, varscan2
- CDON | c.1137G>A p.Q379= | Silent (SNP) | VAF 56/211 reads (27%) | catalogued as rs1466626411; called by muse, mutect2, varscan2
- CDPF1 | c.156C>T p.S52= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs374135528, COSV99416050; called by muse, mutect2, varscan2
- CEACAM5 | c.1992C>A p.R664= | Silent (SNP) | VAF 68/203 reads (33%) | called by muse, mutect2, varscan2
- CLDN19 | c.240G>A p.A80= | Silent (SNP) | VAF 11/220 reads (5%) | catalogued as rs896880334; called by muse, mutect2
- COL28A1 | c.1074A>T p.G358= | Silent (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- COL4A4 | c.4695C>T p.R1565= | Silent (SNP) | VAF 39/144 reads (27%) | called by muse, mutect2, varscan2
- COPG1 | c.2019C>T p.T673= | Silent (SNP) | VAF 40/210 reads (19%) | called by muse, mutect2, varscan2
- CRB1 | c.3399G>A p.V1133= | Silent (SNP) | VAF 70/274 reads (26%) | called by muse, mutect2, varscan2
- CRX | c.777C>T p.G259= | Silent (SNP) | VAF 72/263 reads (27%) | catalogued as rs373752882; called by muse, mutect2, varscan2
- CTSS | c.801C>T p.Y267= | Silent (SNP) | VAF 48/176 reads (27%) | called by muse, mutect2, varscan2
- CXCR3 | c.495G>A p.P165= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs371066158; called by muse, mutect2, varscan2
- DCDC1 | c.3579A>G p.S1193= (on ENST00000597505 / NM_001367979.1; = p.S300= on NM_020869.3) | Silent (SNP) | VAF 27/494 reads (5%) | catalogued as rs745755931; called by muse, mutect2
- DNAH5 | c.6459T>C p.F2153= | Silent (SNP) | VAF 44/269 reads (16%) | called by muse, mutect2, varscan2
- DVL3 | c.1692C>T p.S564= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV53050181; called by muse, mutect2, varscan2
- EDNRB | c.774A>G p.P258= (on ENST00000377211 / NM_001201397.1; = p.P168= on NM_000115.5) | Silent (SNP) | VAF 57/247 reads (23%) | catalogued as rs200392610; called by muse, mutect2, varscan2
- EIF3D | c.606C>T p.Y202= | Silent (SNP) | VAF 52/193 reads (27%) | catalogued as rs145235752; called by muse, mutect2, varscan2
- EIF4G1 | c.1299G>A p.A433= (on ENST00000346169 / NM_198241.3; = p.A237= on NM_004953.5) | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs1206702478; called by muse, mutect2, varscan2
- EPPK1 | c.5700G>A p.A1900= | Silent (SNP) | VAF 89/329 reads (27%) | catalogued as rs775059124, COSV73260951; called by muse, mutect2, varscan2
- ETS2 | c.1182C>T p.A394= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as rs185172042; called by muse, mutect2, varscan2
- EXO1 | c.1968C>T p.S656= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs768579029, COSV62217503; called by muse, mutect2, varscan2
- FAM234B | c.99C>T p.S33= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as rs142634999; called by muse, mutect2, varscan2
- FEV | c.705C>G p.G235= | Silent (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- FGA | c.837C>T p.T279= | Silent (SNP) | VAF 67/206 reads (33%) | catalogued as rs763049586; called by muse, mutect2, varscan2
- FGD6 | c.4176C>T p.S1392= | Silent (SNP) | VAF 24/187 reads (13%) | catalogued as rs756009691; called by muse, mutect2, varscan2
- FHL3 | c.729C>T p.H243= | Silent (SNP) | VAF 14/263 reads (5%) | called by muse, mutect2
- FKRP | c.1200C>T p.G400= | Silent (SNP) | VAF 166/560 reads (30%) | catalogued as COSV100586736; called by mutect2, varscan2
- FLG | c.11910A>G p.S3970= | Silent (SNP) | VAF 149/708 reads (21%) | called by muse, mutect2, varscan2
- FLNA | c.1020C>T p.R340= | Silent (SNP) | VAF 22/587 reads (4%) | called by muse, mutect2
- FUT1 | c.849C>T p.G283= | Silent (SNP) | VAF 91/513 reads (18%) | catalogued as rs1173924525, COSV59567681; called by muse, mutect2, varscan2
- GABBR1 | c.1428C>A p.A476= | Silent (SNP) | VAF 20/329 reads (6%) | called by muse, mutect2
- GAK | c.723C>T p.G241= | Silent (SNP) | VAF 58/245 reads (24%) | called by muse, mutect2, varscan2
- GLIS3 | c.789G>A p.P263= | Silent (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- GPRASP1 | c.2985T>C p.A995= | Silent (SNP) | VAF 17/370 reads (5%) | called by muse, mutect2
- GRIN2B | c.3609C>T p.N1203= | Silent (SNP) | VAF 49/202 reads (24%) | catalogued as COSV74205766, COSV74207639; called by muse, mutect2, varscan2
- GTF2F1 | c.1167G>A p.T389= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as rs770601677; called by muse, mutect2, varscan2
- GYG2 | c.195G>A p.T65= | Silent (SNP) | VAF 51/188 reads (27%) | catalogued as COSV58549802; called by muse, mutect2, varscan2
- HAPLN4 | c.216T>C p.Y72= | Silent (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- HLA-F | c.573A>G p.R191= | Silent (SNP) | VAF 56/218 reads (26%) | called by muse, mutect2, varscan2
- HLA-F | c.852C>T p.H284= | Silent (SNP) | VAF 80/320 reads (25%) | catalogued as rs374197706; called by muse, mutect2, varscan2
- IKZF1 | c.621C>T p.G207= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs1255759479, COSV58784127; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1908C>T p.G636= | Silent (SNP) | VAF 9/131 reads (7%) | called by muse, mutect2
- INHBA | c.636C>T p.D212= | Silent (SNP) | VAF 89/338 reads (26%) | catalogued as rs149369067, COSV99637020; called by muse, mutect2, varscan2
- INTS9 | c.1911C>T p.C637= | Silent (SNP) | VAF 135/448 reads (30%) | catalogued as rs754202366, COSV68434273; called by muse, mutect2, varscan2
- JPH3 | c.1431G>A p.L477= | Silent (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- KCNA5 | c.282G>A p.E94= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs750234815; called by muse, mutect2, varscan2
- KCNB1 | c.270C>T p.G90= | Silent (SNP) | VAF 77/254 reads (30%) | catalogued as rs762279881, COSV65566177, COSV65566453; called by muse, mutect2, varscan2
- KCNH3 | c.2031C>G p.G677= | Silent (SNP) | VAF 64/269 reads (24%) | called by muse, mutect2, varscan2
- KCTD10 | c.621T>C p.I207= | Silent (SNP) | VAF 75/454 reads (17%) | called by muse, mutect2, varscan2
- KIAA1586 | c.1068A>G p.S356= | Silent (SNP) | VAF 35/120 reads (29%) | called by muse, mutect2, varscan2
- KIF26B | c.5172G>A p.S1724= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as rs758215890, COSV63638633; called by muse, mutect2, varscan2
- KLHL34 | c.894C>T p.V298= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- LDB1 | c.9G>T p.V3= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, varscan2
- LMOD3 | c.186G>A p.P62= | Silent (SNP) | VAF 103/345 reads (30%) | catalogued as rs757791893, COSV70455713; ClinVar: likely benign; called by muse, mutect2, varscan2
- LPCAT1 | c.1044T>C p.L348= | Silent (SNP) | VAF 33/171 reads (19%) | called by muse, mutect2, varscan2
- LTB | c.693C>T p.F231= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as rs4248165; called by muse, mutect2
- LYN | c.153A>G p.L51= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as rs762029441; called by muse, mutect2, varscan2
- LZTS2 | c.360C>T p.L120= | Silent (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
- ME3 | c.1353G>A p.T451= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as rs147276864, COSV62772830; called by muse, mutect2, varscan2
- MED27 | c.321C>T p.L107= | Silent (SNP) | VAF 52/193 reads (27%) | catalogued as COSV52603198; called by muse, mutect2, varscan2
- MEPCE | c.834G>A p.G278= | Silent (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- MICAL2 | c.792T>C p.S264= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as rs749560955; called by muse, mutect2, varscan2
- MLST8 | c.768G>A p.T256= | Silent (SNP) | VAF 46/252 reads (18%) | catalogued as rs766079176, COSV57027129; called by muse, mutect2, varscan2
- MROH7 | c.1671T>C p.P557= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as rs1406363251; called by muse, mutect2, varscan2
- MTMR7 | c.1197T>C p.I399= | Silent (SNP) | VAF 35/222 reads (16%) | catalogued as rs1308197548; called by muse, mutect2, varscan2
- MYH8 | c.3450C>T p.S1150= | Silent (SNP) | VAF 100/367 reads (27%) | catalogued as COSV67972220; called by muse, mutect2, varscan2
- NAGS | c.105G>A p.A35= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs771197434; called by muse, mutect2, varscan2
- NEUROD1 | c.102C>T p.H34= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs748626988, COSV99716854, COSV99717080; called by muse, mutect2, varscan2
- NKX1-1 | c.1095C>T p.G365= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- NLRP3 | c.270G>A p.P90= | Silent (SNP) | VAF 100/372 reads (27%) | catalogued as rs771343047, COSV60221367; called by muse, mutect2, varscan2
- OR5L2 | c.405C>T p.T135= | Silent (SNP) | VAF 33/235 reads (14%) | catalogued as rs768407005; called by muse, mutect2, varscan2
- OR9G1 | c.567C>T p.G189= | Silent (SNP) | VAF 35/376 reads (9%) | catalogued as rs770442188, COSV56448164; called by muse, mutect2
- OSBP2 | c.2352G>C p.L784= | Silent (SNP) | VAF 36/137 reads (26%) | called by muse, mutect2, varscan2
- OTUD7A | c.2637G>A p.A879= (on ENST00000307050 / NM_001382637.1; = p.A872= on NM_130901.3) | Silent (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- P3H4 | c.873C>T p.F291= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as rs782457193, COSV58636120; called by muse, mutect2, varscan2
- PADI1 | c.1395G>A p.S465= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as rs766287642, COSV64937828; called by muse, mutect2
- PARD6G | c.201G>A p.V67= | Silent (SNP) | VAF 105/372 reads (28%) | called by muse, mutect2, varscan2
- PCDHGC5 | c.2340G>A p.P780= | Silent (SNP) | VAF 75/352 reads (21%) | catalogued as COSV99339136; called by muse, mutect2, varscan2
- PCSK4 | c.669C>T p.N223= | Silent (SNP) | VAF 55/246 reads (22%) | catalogued as rs767064291, COSV52015377; called by muse, mutect2, varscan2
- PIDD1 | c.1995C>T p.G665= | Silent (SNP) | VAF 23/296 reads (8%) | catalogued as rs151136652; called by muse, mutect2
- PKD1L2 | c.1962C>T p.Y654= | Silent (SNP) | VAF 65/229 reads (28%) | catalogued as rs370855804; called by muse, mutect2, varscan2
- PKHD1 | c.2637G>A p.T879= | Silent (SNP) | VAF 129/396 reads (33%) | catalogued as rs147915980; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PLCH2 | c.939T>C p.A313= | Silent (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- PLEC | c.1935G>A p.L645= (on ENST00000322810 / NM_201380.4; = p.L535= on NM_000445.5) | Silent (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- PLEKHA1 | c.573G>A p.A191= | Silent (SNP) | VAF 50/188 reads (27%) | catalogued as rs528896982; called by muse, varscan2
- PLOD3 | c.2118C>T p.G706= | Silent (SNP) | VAF 63/418 reads (15%) | called by muse, mutect2, varscan2
- PNPLA6 | c.3063G>A p.A1021= (on ENST00000414982 / NM_001166111.2; = p.A973= on NM_006702.5) | Silent (SNP) | VAF 58/212 reads (27%) | catalogued as rs1392152318; called by muse, mutect2, varscan2
- POGLUT2 | c.1347C>T p.G449= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs377423123; called by muse, mutect2, varscan2
- POLR3C | c.759C>T p.S253= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs782225331, COSV61937180; called by muse, mutect2, varscan2
- PPL | c.4893C>T p.L1631= | Silent (SNP) | VAF 61/263 reads (23%) | catalogued as rs1214070398; called by muse, mutect2, varscan2
- PPP3CA | c.1530G>A p.T510= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as rs556579033; called by muse, mutect2, varscan2
- PRR29 | c.534G>A p.P178= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs930749652; called by muse, mutect2, varscan2
- RBM19 | c.2121C>T p.D707= | Silent (SNP) | VAF 54/200 reads (27%) | called by muse, mutect2, varscan2
- RBM42 | c.552C>A p.A184= | Silent (SNP) | VAF 11/276 reads (4%) | called by muse, mutect2
- RBM42 | c.1347G>A p.S449= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as rs764679116; called by muse, mutect2, varscan2
- REV3L | c.8415C>T p.A2805= | Silent (SNP) | VAF 60/207 reads (29%) | catalogued as rs764148865; called by muse, mutect2, varscan2
- RIPK1 | c.171C>T p.N57= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs746827290; called by muse, mutect2, varscan2
- RNF213 | c.6468G>A p.L2156= | Silent (SNP) | VAF 170/562 reads (30%) | called by muse, mutect2, varscan2
- ROR2 | c.2781G>A p.G927= | Silent (SNP) | VAF 29/146 reads (20%) | catalogued as COSV100995535; called by muse, mutect2, varscan2
- RPE65 | c.1194C>T p.D398= | Silent (SNP) | VAF 69/428 reads (16%) | catalogued as rs139640666, COSV52019104; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RUSC1 | c.1566T>C p.D522= (on ENST00000368352 / NM_001105203.2; = p.D53= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- SDK1 | c.3697C>T p.L1233= | Silent (SNP) | VAF 26/494 reads (5%) | called by muse, mutect2
- SEC24B | c.3054C>T p.A1018= | Silent (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- SLC23A3 | c.816C>A p.A272= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- SLC26A1 | c.870G>A p.V290= | Silent (SNP) | VAF 90/334 reads (27%) | catalogued as rs1259316124; called by muse, mutect2, varscan2
- SLC44A2 | c.1467G>A p.P489= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs1212755756, COSV59839242; called by muse, mutect2, varscan2
- SLC4A2 | c.2304A>G p.S768= | Silent (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2, varscan2
- SLC4A9 | c.2809C>T p.L937= (on ENST00000507527 / NM_001258428.2; = p.L913= on NM_031467.3) | Silent (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- SLC51A | c.213T>C p.D71= | Silent (SNP) | VAF 46/217 reads (21%) | called by muse, mutect2, varscan2
- SMG7 | c.2502A>G p.S834= | Silent (SNP) | VAF 89/258 reads (34%) | called by muse, mutect2, varscan2
- SMPDL3B | c.708C>T p.H236= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as rs752394375, COSV65855073; called by muse, mutect2, varscan2
- SNX21 | c.519G>A p.S173= | Silent (SNP) | VAF 101/321 reads (31%) | catalogued as rs752760310, COSV54170699, COSV99467590; called by muse, mutect2, varscan2
- SON | c.3168C>T p.R1056= | Silent (SNP) | VAF 77/319 reads (24%) | called by muse, mutect2, varscan2
- SORBS2 | c.2811C>G p.P937= (on ENST00000284776 / NM_021069.5; = p.P503= on NM_003603.6) | Silent (SNP) | VAF 78/281 reads (28%) | catalogued as rs201889866; called by muse, mutect2, varscan2
- SOX30 | c.543C>T p.D181= | Silent (SNP) | VAF 72/267 reads (27%) | catalogued as COSV53936457, COSV53937669; called by muse, mutect2, varscan2
- SPTBN5 | c.561C>T p.C187= | Silent (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- STAB1 | c.1344G>A p.G448= | Silent (SNP) | VAF 84/264 reads (32%) | catalogued as COSV58732099; called by muse, mutect2, varscan2
- STAB1 | c.3627C>T p.N1209= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- SVEP1 | c.3213G>A p.S1071= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as rs780701958; called by muse, mutect2, varscan2
- TBC1D17 | c.474C>T p.R158= | Silent (SNP) | VAF 84/241 reads (35%) | catalogued as rs776981743; called by muse, mutect2, varscan2
- TBX22 | c.90G>A p.A30= | Silent (SNP) | VAF 80/485 reads (16%) | catalogued as rs773703001, COSV64787072; called by muse, mutect2, varscan2
- TCF15 | c.342G>A p.V114= | Silent (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- TENM1 | c.4731C>T p.G1577= | Silent (SNP) | VAF 81/237 reads (34%) | catalogued as rs199941877; called by muse, mutect2, varscan2
- TMCC2 | c.1203C>T p.G401= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as rs776900750; called by muse, mutect2, varscan2
- TMEM108 | c.765G>A p.A255= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as rs751525194, COSV58865347; called by muse, mutect2, varscan2
- TMEM41A | c.357C>T p.C119= | Silent (SNP) | VAF 62/273 reads (23%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1866C>A p.P622= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
140 further variants in this file (0 protein-altering or splice-affecting, 16 silent, 124 other) are not listed here.
